Somatic mutation profile of tumor specimen 2b4ce90c-8036-4207-ac3e-54a76f (aliquot 2b4ce90c-8036-4207-ac3e-54a76f_D6) from CPTAC case 22OV001, project CPTAC-2 (Retroperitoneum and peritoneum — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Peritoneum, NOS; FIGO stage: Stage IIIC.
Specimen 2b4ce90c-8036-4207-ac3e-54a76f: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 692863d0-c1b9-41f1-8d9a-8f173f49581b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4b216777-ce44-45f7-9df1-9d873a (Blood Derived Normal), aliquot 4b216777-ce44-45f7-9df1-9d873a_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c62317f4-f9a8-4196-9909-ce02479d88c4

The open-access MAF lists 98 somatic variants for this specimen: 70 protein-altering or splice-affecting, 11 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 11, Nonsense Mutation 7, Splice Site 7, Intron 6, 5'UTR 5, 3'UTR 3, RNA 3, Frame Shift Del 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LOXHD1 | c.2870C>A p.S957* | Nonsense Mutation (SNP) | VAF 276/460 reads (60%) | catalogued as rs1440105492; ClinVar: pathogenic; called by mutect2, varscan2
- NSD1 | c.4378+3_4378+6del p.X1460_splice | Splice Site (DEL) | VAF 57/103 reads (55%) | catalogued as rs1562251194; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 214/392 reads (55%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA4 | c.6286G>A p.E2096K | Missense Mutation (SNP) | VAF 204/596 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs61750646, CM990073; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AMBN | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 124/308 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775535240, COSV59827164; called by muse, mutect2, varscan2
- CGNL1 | c.641C>A p.T214K | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV55564915; called by muse, mutect2
- CPNE8 | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100505083; called by muse, mutect2, varscan2
- DMWD | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1408151052; called by muse, mutect2, varscan2
- ELOA2 | c.1058C>A p.T353N | Missense Mutation (SNP) | VAF 125/230 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); catalogued as rs1238530028; called by muse, mutect2, varscan2
- JAKMIP2 | c.314A>T p.K105M | Missense Mutation (SNP) | VAF 375/511 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1435281714; called by muse, mutect2, varscan2
- MISP | c.204C>G p.Y68* | Nonsense Mutation (SNP) | VAF 181/291 reads (62%) | catalogued as rs145024685; called by muse, mutect2, varscan2
- OCIAD1 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99971172; called by muse, mutect2, varscan2
- OPRD1 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 136/368 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52382695; called by muse, mutect2, varscan2
- PATZ1 | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 153/432 reads (35%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.68); catalogued as rs1260313912; called by muse, mutect2, varscan2
- PDPR | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs765130135; called by muse, mutect2, varscan2
- PSG7 | c.134T>A p.V45D | Missense Mutation (SNP) | VAF 93/381 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs782279863; called by muse, mutect2, varscan2
- SIAH2 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 42/752 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV100469043; called by muse, mutect2
- TMCO5A | c.388-1G>A p.X130_splice | Splice Site (SNP) | VAF 69/168 reads (41%) | catalogued as rs367696225, COSV60465772; called by muse, mutect2, varscan2
- TUT4 | c.1078A>T p.I360F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.094); catalogued as rs774785560; called by muse, mutect2
- ZFHX3 | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 176/660 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs773768765, COSV51736263; called by muse, mutect2, varscan2
- ABCD1 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- ALAD | c.477G>C p.K159N | Missense Mutation (SNP) | VAF 621/874 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.114); called by mutect2, varscan2
- BRIX1 | c.43C>G p.Q15E | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASD1 | c.2302A>C p.N768H | Missense Mutation (SNP) | VAF 103/323 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- CBLL1 | c.784G>C p.A262P | Missense Mutation (SNP) | VAF 239/682 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLSTN2 | c.1733T>A p.I578N | Missense Mutation (SNP) | VAF 84/601 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- CRYBG2 | c.3587A>T p.E1196V | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CSMD1 | c.10435A>C p.S3479R (on ENST00000520002; = p.S3478R on NM_033225.6) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- DAGLA | c.549-9_576del p.X183_splice | Splice Site (DEL) | VAF 165/650 reads (25%) | called by mutect2, pindel, varscan2
- DMRTB1 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 92/240 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ELK1 | c.910A>C p.S304R | Missense Mutation (SNP) | VAF 150/402 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.019); called by muse, varscan2
- ENAM | c.589-1_614del p.X197_splice | Splice Site (DEL) | VAF 29/100 reads (29%) | called by mutect2, pindel, varscan2
- ERVV-2 | c.510A>T p.Q170H | Missense Mutation (SNP) | VAF 188/615 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ESRRB | c.51G>C p.K17N | Missense Mutation (SNP) | VAF 237/404 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXOC2 | c.1934T>G p.V645G | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- FAM71F1 | c.32G>C p.W11S | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); called by muse, mutect2
- FNDC1 | c.3598G>C p.V1200L | Missense Mutation (SNP) | VAF 97/216 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FZD8 | c.1166A>C p.E389A | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- HELB | c.2265C>G p.C755W | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- IGFN1 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL18R1 | c.841G>T p.V281L | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA1109 | c.3401G>T p.R1134I | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- MAP3K2 | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- MARK4 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 130/385 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MED30 | c.339A>G p.Q113= | Splice Region (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- MMP16 | c.133G>T p.V45F | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- MUC19 | c.1037C>A p.P346Q | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MUCL1 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 77/117 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRL | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- OR2A4 | c.223A>C p.N75H | Missense Mutation (SNP) | VAF 144/606 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, varscan2
- OR8U1 | c.764T>A p.L255H | Missense Mutation (SNP) | VAF 148/402 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- PCNT | c.4580G>C p.G1527A | Missense Mutation (SNP) | VAF 180/553 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PDE9A | c.263-1G>A p.X88_splice | Splice Site (SNP) | VAF 44/124 reads (35%) | called by muse, mutect2, varscan2
- PIWIL2 | c.2765+1G>T p.X922_splice | Splice Site (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- POLE | c.3845_3846delinsT p.Q1282Lfs*79 | Frame Shift Del (DEL) | VAF 76/571 reads (13%) | called by pindel, varscan2*
- POT1 | c.1385A>T p.E462V | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- POT1 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 55/168 reads (33%) | called by muse, mutect2, varscan2
- PPP4R3C | c.1581C>A p.F527L | Missense Mutation (SNP) | VAF 131/343 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RAB5C | c.166+1G>A p.X56_splice | Splice Site (SNP) | VAF 52/90 reads (58%) | called by muse, mutect2, varscan2
- RABEP1 | c.158A>T p.K53I | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RTL4 | c.919A>T p.T307S | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SNX20 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SYT13 | c.1085T>A p.F362Y | Missense Mutation (SNP) | VAF 149/475 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TMCO5A | c.388G>T p.V130F | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UGT2B15 | c.947del p.N316Tfs*9 | Frame Shift Del (DEL) | VAF 24/159 reads (15%) | called by mutect2, varscan2
- UGT2B17 | c.947del p.N316Tfs*9 | Frame Shift Del (DEL) | VAF 29/107 reads (27%) | called by mutect2, varscan2
- VPS13D | c.4462C>A p.L1488M | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- WWP2 | c.1025C>A p.P342H | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ZNF417 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT tolerated (0.77); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF841 | c.634C>T p.Q212* (on ENST00000426391 / NM_001369830.1; = p.Q328* on NM_001136499.1 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/567 reads (4%) | called by muse, mutect2
- BAG5 | c.237C>G p.L79= | Silent (SNP) | VAF 84/250 reads (34%) | called by muse, mutect2, varscan2
- EDA | c.579T>A p.P193= | Silent (SNP) | VAF 53/188 reads (28%) | catalogued as CD105058; called by muse, mutect2, varscan2
- ELL | c.1377G>A p.E459= | Silent (SNP) | VAF 131/348 reads (38%) | called by muse, mutect2, varscan2
- H2AC20 | c.234C>A p.R78= | Silent (SNP) | VAF 102/439 reads (23%) | called by muse, mutect2, varscan2
- KIAA1210 | c.4536A>T p.V1512= | Silent (SNP) | VAF 20/275 reads (7%) | called by muse, mutect2
- PDZK1 | c.558G>A p.E186= | Silent (SNP) | VAF 102/253 reads (40%) | called by muse, mutect2, varscan2
- RBM10 | c.735G>A p.Q245= | Silent (SNP) | VAF 257/718 reads (36%) | catalogued as COSV61310163; called by muse, mutect2, varscan2
- SHANK1 | c.5517C>G p.P1839= | Silent (SNP) | VAF 112/314 reads (36%) | called by muse, mutect2, varscan2
- SLITRK5 | c.2847G>T p.L949= | Silent (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- ST8SIA3 | c.756T>A p.T252= | Silent (SNP) | VAF 18/181 reads (10%) | called by muse, mutect2
- ZNF688 | c.186G>T p.L62= | Silent (SNP) | VAF 76/217 reads (35%) | called by muse, mutect2, varscan2
- ATP6V0D1 | c.302+1292C>G | Intron (SNP) | VAF 104/282 reads (37%) | called by muse, mutect2, varscan2
- C1orf50 | c.80-31C>T | Intron (SNP) | VAF 53/203 reads (26%) | called by muse, mutect2, varscan2
- CCDC144A | c.*77G>T | 3'UTR (SNP) | VAF 43/97 reads (44%) | catalogued as rs1451038290, COSV100852978; called by muse, mutect2, varscan2
- DUSP14 | c.-1C>T | 5'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, varscan2
- DUSP4 | c.433+4325A>G | Intron (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99529597; called by muse, mutect2, varscan2
- HMOX1 | c.-60A>T | 5'UTR (SNP) | VAF 66/199 reads (33%) | called by muse, mutect2, varscan2
- KIRREL3 | c.55+5194G>A | Intron (SNP) | VAF 182/544 reads (33%) | called by muse, mutect2, varscan2
- LINC02551 | n.1057T>G | RNA (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- MBP | c.-4C>T | 5'UTR (SNP) | VAF 65/187 reads (35%) | called by muse, mutect2, varscan2
- MIR337 | n.7A>T | RNA (SNP) | VAF 141/446 reads (32%) | called by muse, mutect2, varscan2
- MYL4 | c.*15+20C>A | Intron (SNP) | VAF 90/144 reads (63%) | called by muse, mutect2, varscan2
- RHEX | c.-20T>G | 5'UTR (SNP) | VAF 77/230 reads (33%) | called by muse, mutect2, varscan2
- RPL23AP42 | n.191G>C | RNA (SNP) | VAF 26/672 reads (4%) | catalogued as rs1465499286; called by muse, mutect2
- TNFRSF18 | c.*75G>T | 3'UTR (SNP) | VAF 84/218 reads (39%) | catalogued as rs753868857; called by muse, mutect2, varscan2
- TRMT1L | c.-28G>A | 5'UTR (SNP) | VAF 24/100 reads (24%) | catalogued as rs749829855, COSV100833168; called by muse, mutect2, varscan2
- VWA3B | c.1837-1020G>A | Intron (SNP) | VAF 120/328 reads (37%) | called by muse, mutect2, varscan2
- ZNF134 | c.*103C>G | 3'UTR (SNP) | VAF 80/174 reads (46%) | catalogued as COSV101270778; called by muse, mutect2, varscan2
